Somatic mutation profile of tumor specimen BA2663D (aliquot aq-BA2663D) from BEATAML1.0 case 2519, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Chronic myelomonocytic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,625 days).
Specimen BA2663D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e57c01b-f165-40ca-9839-41f633ab9e56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2770D (Solid Tissue Normal), aliquot aq-BA2770D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fbe7f93-911f-48f8-a5d5-02414212e4c2

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRTC2 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57841736; called by muse, mutect2, varscan2
- MTA2 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1401095627; called by muse, varscan2
- PLXNA2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs778558207; called by muse, varscan2
- TRIM11 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- DMXL2 | c.2193C>T p.D731= | Silent (SNP) | VAF 76/206 reads (37%) | called by muse, varscan2
- EIF4G3 | c.4518G>A p.K1506= | Silent (SNP) | VAF 66/181 reads (36%) | called by muse, mutect2, varscan2
- LGI2 | c.577C>T p.L193= | Silent (SNP) | VAF 54/143 reads (38%) | called by muse, mutect2, varscan2
- POM121L12 | c.408G>A p.P136= | Silent (SNP) | VAF 100/204 reads (49%) | catalogued as rs755206617, COSV68692208; called by muse, varscan2
